Gene-level copy-number profile of tumor specimen TCGA-OR-A5LB-01A from TCGA case TCGA-OR-A5LB, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 59.0 years (21,565 days).
Specimen TCGA-OR-A5LB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ACC.a796c599-8450-419f-8a93-b62db685bc07.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-OR-A5LB-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/62f2990a-858e-4015-bf2e-b736d0cc64e1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 102; copy number 2: 33,754; copy number 3: 11; copy number 4: 25,926; copy number 6: 23.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-OR-A5LB-01A-11D-A29H-01): tumor purity 0.96, ploidy 1.44, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:89,047,442–89,482,134, 3 genes (within-gene range 0–2): GAPDHP50, EPHA3, AC109129.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 23 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:25,160,663–25,418,498, 5 genes, copy number 6 (within-gene range 4–6): PI4K2B, AC104662.1, U2, ZCCHC4, ANAPC4.
- chr9:89,639,814–89,719,759, 1 gene, copy number 6: UNQ6494.
- chr14:35,278,633–35,469,330, 7 genes, copy number 6: PSMA6, AL133163.2, AL133163.1, NFKBIA, DNAJC8P1, AL133163.3, RPS3AP4.
- chr14:77,320,996–77,498,816, 9 genes, copy number 6 (within-gene range 4–6): GSTZ1, TMED8, AC007954.1, SAMD15, NOXRED1, VIPAS39, AHSA1, AF111168.1, ISM2.
- chr14:77,547,566–77,547,846, 1 gene, copy number 6: RN7SL587P.

Autosomal genes at a single copy (total copy number 1): 102. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
